Somatic mutation profile of tumor specimen TCGA-05-5429-01A (aliquot TCGA-05-5429-01A-01D-1625-08) from TCGA case TCGA-05-5429, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 60.4 years (22,066 days).
Specimen TCGA-05-5429-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ff570c3-f2f3-46fc-bd84-5054a3b87975.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-5429-10A (Blood Derived Normal), aliquot TCGA-05-5429-10A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45731335-5a61-4e1c-9d19-673daa536742

The open-access MAF lists 36 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 20, Silent 9, Nonsense Mutation 5, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV61683964, COSV61688596, COSV61694890; called by muse, mutect2, varscan2
- ANKRD30A | c.1165G>T p.E389* (on ENST00000611781; = p.E333* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as rs552183541, COSV64610636; called by muse, mutect2, varscan2
- ARHGEF3 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs1161370912, COSV56326471, COSV56326771; called by muse, mutect2, varscan2
- BMP15 | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as rs991314787, COSV53140530; called by muse, mutect2, varscan2
- CD163L1 | c.3469G>C p.E1157Q | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58016431, COSV58016617; called by muse, mutect2, varscan2
- CSF3R | c.1967A>G p.N656S | Missense Mutation (SNP) | VAF 65/136 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV58966940; called by muse, mutect2, varscan2
- DNAJC13 | c.1892+3_1892+6del p.X631_splice | Splice Site (DEL) | VAF 8/60 reads (13%) | catalogued as rs1263135804; called by pindel, varscan2
- EGF | c.2827C>T p.R943C | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs144527372; called by muse, mutect2, varscan2
- EHF | c.342C>G p.N114K | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.999); catalogued as COSV57668234, COSV57669410; called by muse, mutect2, varscan2
- FOXP2 | c.958C>A p.Q320K | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); catalogued as COSV63486358; called by muse, mutect2
- FPR1 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as rs186613919; called by muse, mutect2, varscan2
- GARNL3 | c.95G>A p.G32D | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as COSV59226514; called by muse, mutect2, varscan2
- GKN2 | c.449A>C p.K150T | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV61031251; called by muse, mutect2, varscan2
- KRT7 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as rs374918745; called by muse, mutect2, varscan2
- MARCO | c.1558G>A p.V520I | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.198); catalogued as rs200590124; called by muse, mutect2, varscan2
- MGAT5B | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs537970370, COSV56929535; called by muse, mutect2, varscan2
- PCDHB4 | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs782764025, COSV52022663; called by muse, varscan2
- PHKB | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54521727; called by muse, mutect2, varscan2
- PRB3 | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 13/162 reads (8%) | catalogued as rs533793961, COSV54389356; called by muse, mutect2
- RYR1 | c.2450G>A p.R817Q | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.233); catalogued as rs759902314, COSV62097819; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPAM1 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377689190, COSV56148794; called by muse, mutect2, varscan2
- STAT1 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV63116212; called by muse, mutect2, varscan2
- TMX2 | c.13G>C p.A5P | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.439); catalogued as COSV53554477; called by muse, mutect2
- TRIM58 | c.1302C>G p.Y434* | Nonsense Mutation (SNP) | VAF 95/226 reads (42%) | catalogued as COSV63570321; called by muse, mutect2, varscan2
- TTLL9 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.809); catalogued as rs369485862; called by muse, mutect2, varscan2
- KLHL21 | c.1484dup p.S497Vfs*29 | Frame Shift Ins (INS) | VAF 8/25 reads (32%) | called by pindel, varscan2
- PARPBP | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, varscan2
- ALX4 | c.522G>T p.G174= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as COSV61326351, COSV61326572; called by muse, mutect2, varscan2
- CFH | c.2682G>C p.G894= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV66408696; called by muse, mutect2, varscan2
- CIRBP | c.30T>G p.V10= | Silent (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- DSCAM | c.6030C>A p.T2010= | Silent (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2
- GRID1 | c.1476C>T p.Y492= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as rs149876378, COSV60029368; called by muse, varscan2
- LAMA5 | c.8304C>T p.G2768= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV53360514; called by muse, mutect2, varscan2
- NAT10 | c.1539T>C p.D513= | Silent (SNP) | VAF 55/387 reads (14%) | catalogued as COSV57663903; called by muse, mutect2, varscan2
- SCAF4 | c.717A>G p.T239= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs887039859; called by muse, mutect2, varscan2
- SYNE3 | c.430C>T p.L144= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as COSV62079559; called by muse, mutect2, varscan2
